Somatic mutation profile of tumor specimen ALCH-AEKI-TTP1-A (aliquot ALCH-AEKI-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEKI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,295 days).
Specimen ALCH-AEKI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0df15a-2bf8-48cc-8fb4-459136db0a5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKI-NB1-A (Blood Derived Normal), aliquot ALCH-AEKI-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fa52884-c4db-4cc3-a413-6c7ebbfccc7e

The open-access MAF lists 147 somatic variants for this specimen: 100 protein-altering or splice-affecting, 28 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 28, Intron 7, Nonsense Mutation 7, RNA 6, 5'Flank 3, 5'UTR 2, Frame Shift Del 1, 3'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 30/340 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.1578G>T p.T526= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57901389; called by mutect2, varscan2
- AKR1C1 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as rs1419352822; called by muse, mutect2
- ALPK2 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV64492751, COSV64494034; called by muse, mutect2, varscan2
- AP2M1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53048391; called by muse, mutect2, varscan2
- CASZ1 | c.1315A>G p.T439A | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59734330; called by muse, mutect2
- CFAP46 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV63954832; called by muse, mutect2
- CIAO3 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV52402161; called by muse, mutect2, varscan2
- CSPG4 | c.3136G>A p.D1046N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552897521; called by muse, mutect2, varscan2
- DIAPH3 | c.3215G>T p.G1072V (on ENST00000400324 / NM_001042517.2; = p.G809V on NM_030932.3) | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57364683; called by muse, mutect2, varscan2
- EGFL8 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs141849753; called by muse, mutect2
- GTF3C1 | c.6016A>G p.M2006V | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1041775412; called by muse, mutect2
- HOXA2 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 22/326 reads (7%) | catalogued as COSV56065683; called by muse, mutect2
- IQCF1 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58824091; called by muse, mutect2
- KEAP1 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260458, COSV50275012, COSV50315065; called by muse, mutect2, varscan2
- MMP16 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs956723755; called by muse, mutect2
- MTM1 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs782364557, COSV60334680; called by muse, mutect2, varscan2
- NPAP1 | c.1184C>A p.T395N | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as COSV100274699; called by muse, mutect2
- NTM | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs1415605524, COSV66181961, COSV66185563; called by muse, mutect2, varscan2
- PCDH15 | c.2031C>G p.D677E | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs770957641; called by muse, mutect2
- PCDHGA6 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); catalogued as COSV53980207; called by muse, mutect2
- PDCD11 | c.1653G>T p.R551S | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.017); catalogued as COSV63934481; called by muse, mutect2
- SI | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs943419067; called by muse, mutect2, varscan2
- SLC16A1 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as rs761211321, COSV100856069; called by muse, mutect2
- SPRING1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV54339528; called by muse, mutect2, varscan2
- WDFY3 | c.2797C>G p.Q933E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV55693413, COSV99884011; called by muse, mutect2, varscan2
- WTIP | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs922344256, COSV54328022; called by muse, mutect2
- ZEB2 | c.1208T>A p.L403H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV57955821; called by muse, mutect2, varscan2
- ZNF398 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60065946; called by muse, mutect2
- ADGRG1 | c.2003G>C p.G668A | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AIM2 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.1); called by muse, mutect2
- ANK2 | c.6773C>A p.T2258N | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2
- ARHGEF10 | c.3026C>T p.S1009F (on ENST00000398564; = p.S984F on NM_014629.4) | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2
- BUB1B | c.595C>G p.R199G | Missense Mutation (SNP) | VAF 28/495 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- C16orf96 | c.2170C>A p.P724T | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- CCDC170 | c.310A>G p.R104G | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP5 | c.2835G>T p.R945S | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2
- COL3A1 | c.3112G>A p.G1038S | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL3A1 | c.3199A>C p.S1067R | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); called by muse, mutect2
- CR1 | c.2381del p.G794Efs*12 | Frame Shift Del (DEL) | VAF 17/162 reads (10%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.4012A>T p.K1338* | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- DIAPH3 | c.3214G>T p.G1072W (on ENST00000400324 / NM_001042517.2; = p.G809W on NM_030932.3) | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3B | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2
- ELANE | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- EYA1 | c.42T>A p.S14R | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- GDF6 | c.1197C>A p.N399K | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR161 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GTF3C1 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HAS2 | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECTD3 | c.1651A>G p.M551V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by mutect2, varscan2
- IL16 | c.2914T>C p.S972P (on ENST00000302987 / NM_172217.5; = p.S271P on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2
- IRS1 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- IZUMO3 | c.556G>T p.V186L (on ENST00000543880 / NM_001365008.2; = p.V180L on NM_001271706.1) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2
- KIAA0895L | c.1016A>T p.Y339F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIF23 | c.1860A>T p.E620D | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2
- KLF2 | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL42 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- KRT28 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- L1CAM | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LIG4 | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- LINGO2 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- LRP2 | c.12802G>A p.A4268T | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- MAGEB18 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MC2R | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MGAT4C | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2
- MTDH | c.1473G>C p.K491N | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MTMR7 | c.1621-1G>C p.X541_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- NPC1L1 | c.3310A>T p.T1104S | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NRXN3 | c.1860C>A p.S620R (on ENST00000335750 / NM_001330195.2; = p.S247R on NM_004796.6) | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR6B1 | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OXCT1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDH15 | c.4493A>C p.E1498A (on ENST00000644397 / NM_001354429.2; = p.N1459H on NM_001142770.3) | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.859); called by muse, mutect2
- PLCH1 | c.1906G>C p.V636L (on ENST00000340059 / NM_001130960.2; = p.V648L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PRC1 | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- PRKAR2B | c.1087G>C p.A363P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRN | c.2034G>A p.W678* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- PZP | c.1586A>G p.D529G | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RAC2 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPB | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2
- RICTOR | c.2398A>T p.K800* | Nonsense Mutation (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- RYR2 | c.6739G>T p.V2247L | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.872); called by muse, mutect2
- SEMA3A | c.368C>A p.A123E | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- SEMA3D | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 19/424 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- SLC12A3 | c.638C>A p.P213Q | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A4 | c.573C>G p.Y191* | Nonsense Mutation (SNP) | VAF 23/188 reads (12%) | called by muse, mutect2
- SLC9A2 | c.1841A>T p.Q614L | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2
- SPATA31A1 | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 70/567 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- STARD7 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TAOK3 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- TRAF5 | c.205A>T p.I69F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIP13 | c.1160T>C p.V387A | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- TSEN54 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- TYR | c.1208G>T p.R403M | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- VCAN | c.4954A>C p.M1652L | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- VCAN | c.6944T>A p.V2315E | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- WDR87 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- YWHAE | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZC3H6 | c.2203A>T p.T735S | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF548 | c.899A>G p.Q300R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- A1CF | c.409C>A p.R137= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as COSV50960172, COSV51051044; called by muse, mutect2
- ABCA1 | c.6741C>T p.L2247= | Silent (SNP) | VAF 13/387 reads (3%) | catalogued as COSV66069536; called by muse, mutect2
- ANKRD44 | c.1785C>T p.I595= | Silent (SNP) | VAF 14/290 reads (5%) | catalogued as rs1426507983; called by muse, mutect2
- DHRS7 | c.57G>A p.L19= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- DIAPH3 | c.2391G>T p.R797= (on ENST00000400324 / NM_001042517.2; = p.R534= on NM_030932.3) | Silent (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- DTHD1 | c.318C>T p.N106= (on ENST00000456874; = p.N231= on NM_001170700.3) | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs1038624277; called by muse, mutect2
- EDIL3 | c.1395G>A p.G465= | Silent (SNP) | VAF 18/392 reads (5%) | catalogued as rs1380194724; called by muse, mutect2
- GABBR2 | c.606G>C p.T202= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs200832069, COSV52293442; called by muse, mutect2
- GRIK2 | c.519G>T p.T173= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- GTF3C4 | c.1642T>C p.L548= | Silent (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- LDLRAD1 | c.159C>A p.L53= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2
- MARK2 | c.1260T>G p.S420= (on ENST00000402010 / NM_001039469.2; = p.S419= on NM_004954.5) | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, varscan2
- MICALL1 | c.1797C>T p.G599= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1242384939; called by muse, mutect2
- NLRP14 | c.1764G>A p.E588= | Silent (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
- NOTCH1 | c.3792T>C p.C1264= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- NR1I2 | c.1173G>A p.L391= | Silent (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- OR2M5 | c.786C>A p.P262= | Silent (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- OR5M10 | c.144G>T p.L48= | Silent (SNP) | VAF 47/363 reads (13%) | called by muse, mutect2, varscan2
- OXTR | c.1023G>A p.V341= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as rs1328706913; called by muse, mutect2, varscan2
- PTCD1 | c.270G>C p.G90= | Silent (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- RCVRN | c.267C>A p.A89= | Silent (SNP) | VAF 25/175 reads (14%) | called by muse, mutect2, varscan2
- SHCBP1L | c.1260A>C p.G420= | Silent (SNP) | VAF 36/315 reads (11%) | called by muse, mutect2, varscan2
- SLC18A2 | c.198G>T p.V66= | Silent (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- SPATA2L | c.606G>A p.R202= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, varscan2
- SVEP1 | c.5461T>C p.L1821= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- SYCP2 | c.2172T>C p.F724= | Silent (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- TAF4 | c.2382G>A p.V794= | Silent (SNP) | VAF 15/251 reads (6%) | called by muse, mutect2
- USH2A | c.10737C>T p.S3579= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- ANKRD49 | c.258+22G>T | Intron (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- AP000281.2 | chr21:32851806 T>C | 5'Flank (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3436G>C | Intron (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.-11C>T | 5'UTR (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- CEP20 | chr16:15888606 C>A | 5'Flank (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- CHD3 | c.5591-33C>G | Intron (SNP) | VAF 19/154 reads (12%) | called by mutect2, varscan2
- CLUHP11 | n.776C>A | RNA (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- GALNS | c.422+38C>G | Intron (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.97C>T | RNA (SNP) | VAF 13/146 reads (9%) | catalogued as rs779310445; called by muse, mutect2
- KCNQ2 | c.817-15C>A | Intron (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- LRATD1 | c.*563G>C | 3'UTR (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2
- NAGA | c.-5G>A | 5'UTR (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- OR1D4 | n.86G>C | RNA (SNP) | VAF 53/604 reads (9%) | called by muse, mutect2
- PAX8 | c.1189+23G>C | Intron (SNP) | VAF 24/273 reads (9%) | called by muse, mutect2
- SETD4 | c.207+24G>C | Intron (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- SNORD114-31 | chr14:100989069 T>A | 5'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- SNORD115-29 | n.72C>T | RNA (SNP) | VAF 32/259 reads (12%) | catalogued as rs374847172; called by muse, mutect2, varscan2
- TBC1D3P2 | n.102C>A | RNA (SNP) | VAF 16/376 reads (4%) | called by muse, mutect2
- ZNF812P | n.943G>A | RNA (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
